Gene-level copy-number profile of tumor specimen TCGA-43-5668-01A from TCGA case TCGA-43-5668, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 78.4 years (28,635 days).
Specimen TCGA-43-5668-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.2e73d049-49bf-4f34-8cf5-6b08eeb65901.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-43-5668-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9118ef03-59e3-40ba-b70d-39da3b4b5e5c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3,087; copy number 2: 19,680; copy number 3: 19,222; copy number 4: 11,623; copy number 5: 3,176; copy number 6: 2,493; copy number 7: 224; copy number 8: 31; copy number 9: 3; copy number 10: 21; copy number 11: 167; copy number 12: 2; copy number 15: 37; copy number 16: 8; copy number 19: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-43-5668-01A-01D-1631-01): tumor purity 0.34, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 530 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:178,028,130–179,240,093, 13 genes, copy number 8: AC110992.1, AC117453.1, KCNMB2, AC117457.1, LINC01014, RNA5SP148, PPIAP75, KCNMB2-AS1, ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1.
- chr5:1,201,595–1,551,710, 14 genes, copy number 10: SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2.
- chr5:42,423,439–42,924,535, 12 genes, copy number 7: GHR, SERBP1P6, AC093225.1, AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6.
- chr5:52,282,567–53,487,134, 18 genes, copy number 8: RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC027329.1, AC108114.1, FST.
- chr7:9,981,516–11,832,198, 17 genes, copy number 10–16 (within-gene range 4–16): AC004936.1, AC004879.1, U3, MGC4859, HSPA8P8, AC009945.1, AC004415.1, Y_RNA, NDUFA4, AC007029.1, PHF14, RPL23AP52, AC004160.1, NPM1P11, THSD7A, AC004160.2, THRAP3P3.
- chr8:29,067,278–29,263,124, 1 gene, copy number 7 (within-gene range 5–7): KIF13B.
- chr8:29,110,573–30,083,467, 20 genes, copy number 7: AC108449.1, HMGB1P23, DUSP4, AC084262.2, AC084262.1, AC084026.2, AC084026.1, AC084026.3, RPL17P33, LINC00589, LINC02099, AC131254.1, AC131254.3, AC131254.2, LINC02209, MIR3148, MAP2K1P1, RNU6-1218P, SARAF, AC044849.1.
- chr11:24,496,970–25,141,023, 3 genes, copy number 9 (within-gene range 3–9): LUZP2, AC115990.1, AC087373.1.
- chr18:47,390–6,915,716, 139 genes, copy number 11–19 (within-gene range 1–19) (broad region; genes not listed).
- chr18:11,326,270–14,139,272, 102 genes, copy number 11 (broad region; genes not listed).
- chr19:13,731,760–17,214,537, 191 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,626. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
